Surgical pathology report (de-identified scan), TCGA case TCGA-MJ-A68H, project TCGA-SARC (Sarcoma), tissue source site BLN - Baylor, specimen TCGA-MJ-A68H-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Accession #:

ed:

ICD-O-3

Leiomyosarcoma NOS
8890/3

Site C&C
Site Retroperitoneum
path C48.0
Retrovaginal septum
C76.3
9/25/21/13

PATHOLOGIC DIAGNOSIS

A. SIGMOID COLON, RECTUM, ANAL CANAL, ANUS AND POSTERIOR VAGINA, ABDOMINOPERINEAL RESECTION WITH EN-BLOC POSTERIOR VAGINECTOMY:

- LEIOMYOSARCOMA (SEE SYNOPTIC REPORT BELOW)
- TUMOR EXTENDS INTO POSTERIOR VAGINAL SOFT TISSUE
- ALL MARGINS ARE NEGATIVE
- TUMOR DOES NOT INVOLVE RECTAL OR ANAL MUCOSA
- FOUR BENIGN LYMPH NODES IDENTIFIED (0/4)
- NO LYMPHOVASCULAR INVASION IDENTIFIED
- NO PERINEURAL INVASION IDENTIFIED

B. POSTERIOR VAGINAL WALL, EXCISION OF NEW MARGIN:
- NO DIAGNOSTIC PATHOLOGIC ALTERATION IDENTIFIED

TUMOR SYNOPTIC REPORT:

Procedure: Abdominoperineal resection with en-block posterior vaginectomy

Tumor Site: Rectovaginal septum region

Tumor Size: 5.0 x 4.7 x 4.0 cm

Macroscopic Extent of Tumor:

Superficial: Dermal and subcutaneous / suprafascial

Deep: Rectovaginal region

Histological Type: Leiomyosarcoma

Mitotic Rate: 17/10 high-power field

Necrosis: Present, less than 20%

Histologic grade (FNCLCC): Grade 2

Margins: Margins negative for sarcoma

Distance of sarcoma from closest margin: 7 mm from anterior inked margin (Part A)

Preresection Treatment: No therapy

Treatment Effect: Not applicable

PATHOLOGIC STAGING:

Primary Tumor: pT1b

[page 2 of 4]
Regional Lymph Node: pN0
Number of lymph nodes examined: 4
Number of lymph nodes involved: 0
Distant Metastasis: Not applicable
Pathological Stage: Stage IA

Staff Pathologist

Comment

A Desmin immunohistochemistry stain is performed on a representative section of tumor. The control is appropriate. The tumor is strongly positive for Desmin, an expected result for leiomyosarcoma.

Intraoperative Consultation

Intraoperative Gross Consultation Diagnosis:

Perineal mass, low anterior resection:

- Tumor identified, approaching but not involving posterior vaginal wall - present for diagnosis, later reviewed by

Staff Pathologist

Pathology Resident

Pertinent Clinical Information

Pertinent History: A year-old BF with perineal mass; previous open (incisional) biopsy > leiomyosarcoma.

Request Intraoperative Consultation. Evaluate the gross margin.

Gross Description

Specimen Material: A. Colon, sigmoid, rectum, anal canal and anus: B. Vagina, posterior vaginal wall:

Part A. Received fresh for intraoperative gross consultation labeled as "SIGMOID, RECTUM, ANAL CANAL, AND ANUS," is a portion of colon with attached posterior vaginal wall, labia majora and anus. The colon is 31 x 7 x 2 cm, the skin ellipse is tan-brown measuring 4 x 8 cm with a 2.6 x 2.5 cm ulcer with rolled borders, which is the previous biopsy site. The anus is sutured closed.

The colon is opened and the mass within the vaginal tissue is bisected. The

[page 3 of 4]
surface of the colon is tan-brown and unremarkable. Anterior to the colon and extending from the vaginal soft tissue is a well-circumscribed white, whirled rubbery mass which is located 21 cm from the proximal margin, 6 cm from the anus, and 1 cm from the anterior inked surface. The fibrous cut surface of the tumor is adjacent to the rectal mucosa. The tumor appears to be locally confined. The pericolonic adipose tissue is dissected to reveal 26 possible lymph nodes ranging in size from 0.2 cm to 1.0 cm.

Ink code:

Blue: Anterior surface of the colon

Black: Vaginal/anal skin ellipse, 12 to 3 to 6 o'clock

Orange: Vaginal/anal skin ellipse, 6 to 9 to 12 o'clock

Representative sections are submitted as follows:

- A1: Proximal margin
- A2: Vaginal and anal skin margin at 12 to 1 o'clock
- A3: Vaginal and anal skin margin from 1 to 2 o'clock
- A4: Vaginal and anal skin margin from 2 to 3 o'clock
- A5: Vaginal and anal skin margin from 3 to 4 o'clock
- A6-A7: Vaginal and anal skin margin from 4 to 5 o'clock
- A8: Vaginal and anal skin margin from 5 to 6 o'clock
- A9: Vaginal and anal skin margin from 6 to 7 o'clock
- A10: Vaginal and anal skin margin from 7 to 8 o'clock
- A11: Vaginal and anal skin margin from 8 to 9 o'clock
- A12: Vaginal and anal skin margin from 9 to 11 o'clock
- A13: Vaginal and anal skin margin from 11 to 12 o'clock
- A14-18: Full thickness of tumor
- A19: Biopsy site ulcer
- A20: Tumor with posterior vagina, anterior inked surface and rectum
- A21-A22: Sections of rectum at dentate line
- A23-24: Tumor adjacent to bowel
- A25: Five possible whole lymph nodes in a filter bag
- A26: Five possible whole lymph nodes in a filter bag
- A27: Five possible whole lymph nodes
- A28: Five possible whole lymph nodes
- A29: Four possible whole lymph nodes
- A30: Two possible whole lymph nodes

Part B. Received in formalin labeled "POSTERIOR VAGINAL WALL - SUTURE MARKS NEW MARGIN," is a 3.3 x 1 x 0.9 cm tan-brown piece of tissue with a suture marking the true margin, as oriented by the surgeon. The specimen is serially sectioned to reveal tan-white fibrous surface with focal hemorrhage. The new true margin is inked blue. The specimen is submitted in its entirety in cassettes B1-B3.

[page 4 of 4]
Pathology Resident
Microscopic Description
A and B: Performed.

The staff pathologist listed below has reviewed this case.

This immunohistochemistry test(s) was developed and its performance characteristics determined by the Immunohistochemistry Laboratory and/or affiliated institution. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

Pathology Resident
Electronically Signed Out

Staff Pathologist

W 5/9/13

Source: NCI Genomic Data Commons file 1b17d05a-d421-43e8-859e-fd3dfbf54914 (TCGA-MJ-A68H.8D7F6617-584B-42DE-90D6-63228F146FAC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).